Somatic mutation profile of tumor specimen TARGET-20-PATDIC-09A (aliquot TARGET-20-PATDIC-09A-01D) from TARGET case TARGET-20-PATDIC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.2 years (4,810 days).
Specimen TARGET-20-PATDIC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8b5538b-1de6-4b2f-8192-afe80e7a83d5.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATDIC-14A (Bone Marrow Normal), aliquot TARGET-20-PATDIC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3aa73ba8-4da2-4184-a7fe-2b980d2c5994

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Splice Region 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.11415G>T p.M3805I | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, varscan2
- PTPRE | c.1464+3_1464+4insG | Splice Region (INS) | VAF 27/103 reads (26%) | called by mutect2, pindel, varscan2
- ANKRD30A | c.1527A>T p.I509= (on ENST00000611781; = p.I453= on NM_052997.2) | Silent (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- PCDHB16 | c.1341C>T p.N447= | Silent (SNP) | VAF 48/111 reads (43%) | catalogued as rs782720287; called by muse, mutect2, varscan2
- SPEG | c.774C>T p.S258= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs776604424; called by muse, mutect2, varscan2
